Somatic mutation profile of tumor specimen 0DTGDE from CCDI case PBCJWH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,449 days).
Specimen 0DTGDE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ead40d97-469a-46c4-bea6-3bb1043ccd4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTGDJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ded90735-5fcf-4a12-8bfa-b6f37cc1543b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMD2 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 63/792 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778988730; called by muse, mutect2
- CFAP44 | c.1870A>G p.M624V | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
